Somatic mutation profile of tumor specimen C3N-08901-01 (aliquot CPT0495570010) from CPTAC case C3N-08901, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 70.8 years (25,857 days).
Specimen C3N-08901-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51b6ed8c-b5d4-47fd-8021-1aba33604260.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08901-31 (Blood Derived Normal), aliquot CPT0495660006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84c92b02-e121-4e85-8e19-0879aeed60c6

The open-access MAF lists 340 somatic variants for this specimen: 220 protein-altering or splice-affecting, 107 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 107, Nonsense Mutation 16, Intron 9, Frame Shift Del 6, In Frame Del 3, Splice Region 2, 5'Flank 2, 5'UTR 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYL2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397516406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4915G>A p.D1639N (on ENST00000272895 / NM_173076.3; = p.D1321N on NM_015657.3) | Missense Mutation (SNP) | VAF 55/370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886055608, COSV55953057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRF3 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs1175643050; called by muse, mutect2, varscan2
- ADGRV1 | c.9860C>T p.S3287L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1169367531, COSV101315792, COSV101316496; called by muse, mutect2, varscan2
- ALG13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as rs767326994, COSV52636707; called by muse, mutect2, varscan2
- AMY2B | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs770135582, COSV63714862; called by muse, mutect2, varscan2
- ANGPTL5 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57531879, COSV57534940; called by muse, mutect2, varscan2
- ANKRD11 | c.6290C>T p.P2097L | Missense Mutation (SNP) | VAF 82/534 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV56366418; called by muse, mutect2, varscan2
- ASNS | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 58/293 reads (20%) | catalogued as COSV51553415; called by muse, mutect2, varscan2
- ATP8A1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs756498988; called by muse, mutect2, varscan2
- BTNL3 | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as rs776457442; called by muse, mutect2, varscan2
- C16orf86 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 58/439 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1044449521; called by muse, mutect2, varscan2
- C19orf44 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as rs978385990; called by muse, mutect2, varscan2
- CAMKV | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as COSV99616150; called by muse, mutect2, varscan2
- CASQ2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | catalogued as rs754834466; called by muse, mutect2, varscan2
- CELA3B | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs758917123, COSV61405968; called by muse, mutect2, varscan2
- CFAP300 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs538201508, COSV71570811, COSV71570860; called by muse, mutect2, varscan2
- CFAP47 | c.8230C>T p.P2744S | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66217386; called by muse, mutect2, varscan2
- CNTN4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.081); catalogued as COSV61882376; called by muse, mutect2, varscan2
- CNTNAP5 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs748756941, COSV101444234; called by muse, mutect2, varscan2
- COL1A1 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 62/431 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs771918127; called by muse, mutect2, varscan2
- COL20A1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 80/714 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1361397643, COSV58924653; called by muse, mutect2, varscan2
- COL23A1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.18); catalogued as rs530588654; called by muse, mutect2, varscan2
- COL6A6 | c.3572G>A p.G1191E | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62023286; called by muse, mutect2, varscan2
- CSF2RB | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 77/457 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs756516150, COSV53259618, COSV99453880; called by muse, mutect2, varscan2
- CYP4F8 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs754898548; called by muse, mutect2, varscan2
- DAP3 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100546595; called by muse, mutect2, varscan2
- DHRS2 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs746044130; called by muse, mutect2, varscan2
- DIRAS1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60214877; called by muse, mutect2, varscan2
- DNAH17 | c.4936G>A p.E1646K | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.476); catalogued as rs757310636; called by muse, mutect2, varscan2
- EIF2B2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 82/471 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99837795; called by muse, mutect2, varscan2
- EN2 | c.908del p.T303Rfs*50 | Frame Shift Del (DEL) | VAF 108/398 reads (27%) | catalogued as COSV52084333; called by mutect2, pindel*, varscan2
- EPN3 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 74/468 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143210632; called by muse, mutect2, varscan2
- ERBB2 | c.3716G>A p.G1239E | Missense Mutation (SNP) | VAF 69/449 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs760307857; called by muse, mutect2, varscan2
- ERC2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs373620783, COSV104384435; called by muse, mutect2, varscan2
- FAM114A2 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752487539; called by muse, mutect2, varscan2
- FBXL13 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as rs750994268, COSV57542560; called by muse, mutect2
- FSIP2 | c.18881C>T p.S6294L | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766201995, COSV58094425; called by muse, mutect2, varscan2
- GABRA2 | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 19/172 reads (11%) | catalogued as COSV62914021; called by muse, mutect2, varscan2
- GIMAP8 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 116/452 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs540607407; called by muse, mutect2, varscan2
- GIPC3 | c.868C>T p.R290C (on ENST00000644946; = p.S285= on NM_133261.3) | Missense Mutation (SNP) | VAF 81/475 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs766192644, COSV59260175; called by muse, mutect2, varscan2
- GLT8D2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 35/221 reads (16%) | catalogued as rs756277684; called by muse, mutect2, varscan2
- GPATCH1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99403726; called by muse, mutect2, varscan2
- GRIA1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as rs1335115184, COSV53594707; called by muse, varscan2
- GRIN2A | c.3536C>T p.S1179F | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV58023841; called by muse, mutect2, varscan2
- GUCY1A1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs758601098, COSV56656283; called by muse, mutect2, varscan2
- HNRNPCL2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.542); catalogued as COSV60402233; called by muse, mutect2
- IDO1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.904); catalogued as COSV53714036; called by muse, mutect2, varscan2
- IGSF21 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs200292815, COSV52129504, COSV52141695; called by muse, mutect2, varscan2
- LARP1B | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1408258686, COSV52802215; called by muse, mutect2, varscan2
- LRP1B | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 23/203 reads (11%) | catalogued as rs1468063300, COSV101258010, COSV67200622; called by muse, mutect2, varscan2
- LRRC28 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs866172183; called by muse, mutect2, varscan2
- LRRC29 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 59/429 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs199620893; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2, varscan2
- LRRN2 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 155/547 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.562); catalogued as rs778992127; called by muse, mutect2, varscan2
- MAPK7 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 94/563 reads (17%) | catalogued as COSV55190815; called by muse, mutect2, varscan2
- ME3 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 107/415 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.89); catalogued as COSV100661138; called by muse, mutect2, varscan2
- MELK | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV53203171; called by muse, mutect2, varscan2
- METTL25 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | catalogued as rs1283456243, COSV50257441; called by muse, mutect2, varscan2
- MRC2 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1052806798; called by muse, mutect2, varscan2
- MST1R | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 94/513 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV56573328; called by muse, mutect2, varscan2
- MT1G | c.28+1G>A p.X10_splice | Splice Site (SNP) | VAF 38/270 reads (14%) | catalogued as rs373407281; called by muse, mutect2, varscan2
- MYBPC3 | c.1623G>A p.Q541= | Splice Region (SNP) | VAF 68/407 reads (17%) | catalogued as rs781764759; called by muse, mutect2, varscan2
- MYO18B | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 69/487 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.563); catalogued as COSV59140619; called by muse, mutect2, varscan2
- NCR2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs370949899; called by muse, mutect2, varscan2
- NDUFAF4 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753857427; called by muse, mutect2, varscan2
- NEB | c.7277C>T p.P2426L | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51107198; called by muse, mutect2, varscan2
- NEBL | c.2596C>T p.L866F | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs373721327; called by muse, mutect2, varscan2
- NINL | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV54006130; called by muse, mutect2, varscan2
- NOS1 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 54/500 reads (11%) | catalogued as COSV57608861; called by muse, mutect2
- OR10G2 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV101606962; called by muse, mutect2
- OR4A15 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 103/411 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); catalogued as rs200450197, COSV59033519; called by muse, mutect2, varscan2
- OR4K1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53460913; called by muse, mutect2, varscan2
- OR4K1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1350015141; called by muse, mutect2, varscan2
- OR51B5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs754820149, COSV56175739; called by muse, mutect2, varscan2
- OR52I2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 159/649 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57046158; called by muse, mutect2, varscan2
- OR5AC2 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62279940; called by muse, varscan2
- OR5G3 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 106/402 reads (26%) | catalogued as rs999279193; called by muse, mutect2, varscan2
- PCARE | c.3641C>T p.S1214F | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.276); catalogued as rs1208161347; called by muse, mutect2, varscan2
- PCSK1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 67/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99081780; called by muse, mutect2, varscan2
- PLEC | c.9298G>A p.V3100M (on ENST00000322810 / NM_201380.4; = p.V2990M on NM_000445.5) | Missense Mutation (SNP) | VAF 77/407 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs782732681; called by muse, mutect2, varscan2
- PLXNA4 | c.5523G>A p.M1841I | Missense Mutation (SNP) | VAF 118/462 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100323736; called by muse, mutect2, varscan2
- POU3F3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 83/524 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100796878; called by muse, mutect2, varscan2
- PRF1 | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 89/426 reads (21%) | catalogued as rs1349520883; called by muse, mutect2, varscan2
- PSG8 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as rs1222833818, COSV60612364, COSV60614700; called by muse, mutect2, varscan2
- RAPGEF4 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as rs1306737616, COSV99075372; called by muse, mutect2, varscan2
- RCAN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201045399, COSV57815863; called by muse, mutect2, varscan2
- RCN3 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 78/532 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760046218; called by muse, mutect2, varscan2
- RGS7BP | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs1169594574; called by muse, mutect2, varscan2
- RYR3 | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 57/330 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV101213246, COSV66791300; called by muse, mutect2, varscan2
- SCNN1D | c.535C>T p.P179S (on ENST00000338555; = p.P343S on NM_001130413.4) | Missense Mutation (SNP) | VAF 93/629 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1391452543; called by muse, mutect2, varscan2
- SEMA6C | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1343534003; called by muse, mutect2, varscan2
- SHROOM1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1285443310, COSV60581334; called by muse, mutect2, varscan2
- SPTA1 | c.4387G>A p.D1463N | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV100935312; called by muse, mutect2, varscan2
- SYN1 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV55983662; called by muse, mutect2, varscan2
- SYT10 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57337864; called by muse, mutect2, varscan2
- TAF1L | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 97/450 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54263867; called by muse, mutect2, varscan2
- TAF1L | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 80/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1323541304; called by muse, mutect2, varscan2
- TBC1D9B | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs149901807; called by muse, mutect2, varscan2
- TBX3 | c.1204G>A p.E402K (on ENST00000257566 / NM_016569.4; = p.E382K on NM_005996.4) | Missense Mutation (SNP) | VAF 77/508 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV57474338; called by muse, mutect2, varscan2
- TDP1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100187696; called by muse, mutect2, varscan2
- TEX26 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1290997006; called by muse, mutect2, varscan2
- TIE1 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 86/464 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs371336996; called by muse, mutect2, varscan2
- TMEM39B | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868721112, COSV100298237; called by muse, mutect2, varscan2
- TRHDE | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53834809, COSV53846369; called by muse, mutect2, varscan2
- TRIOBP | c.4127C>T p.P1376L | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV60380879; called by muse, mutect2, varscan2
- UHRF1BP1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV51952320; called by muse, mutect2, varscan2
- VSIG8 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV63652459; called by muse, mutect2, varscan2
- WRAP53 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755512125, COSV99872646; called by muse, mutect2, varscan2
- XIRP1 | c.4420C>T p.L1474F | Missense Mutation (SNP) | VAF 66/485 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs772941605; called by muse, mutect2, varscan2
- ZBTB46 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 84/670 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761577744; called by muse, mutect2, varscan2
- ZFHX4 | c.7699C>T p.H2567Y | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.715); catalogued as COSV51502970, COSV99268479; called by muse, mutect2, varscan2
- ZNF280C | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63969494; called by muse, mutect2, varscan2
- ABCA4 | c.6477C>T p.S2159= | Splice Region (SNP) | VAF 42/383 reads (11%) | called by muse, mutect2, varscan2
- ABCA6 | c.2198A>C p.D733A | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ACACA | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACRBP | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 111/484 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ADAM20 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 74/460 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ADD2 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADH1A | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALK | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- AMMECR1L | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ANHX | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ANKRD31 | c.3877C>T p.P1293S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANKS3 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APLP2 | c.1843C>G p.Q615E | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARMCX2 | c.948_956del p.A321_A323del | In Frame Del (DEL) | VAF 99/492 reads (20%) | called by mutect2, pindel, varscan2
- ATP2A3 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ATP2B2 | c.2086G>A p.D696N (on ENST00000352432; = p.D662N on NM_001683.5) | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP8A2 | c.2361_2364del p.C788Kfs*16 | Frame Shift Del (DEL) | VAF 39/248 reads (16%) | called by mutect2, pindel, varscan2
- BAG5 | c.64_72del p.S22_E24del | In Frame Del (DEL) | VAF 38/356 reads (11%) | called by mutect2, pindel, varscan2
- BEND5 | c.476T>A p.V159D | Missense Mutation (SNP) | VAF 79/570 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- BUB1B | c.2908C>T p.Q970* | Nonsense Mutation (SNP) | VAF 66/415 reads (16%) | called by muse, mutect2, varscan2
- C16orf86 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C17orf97 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 97/529 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C3 | c.3347G>A p.G1116E | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA5A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASQ2 | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CATSPERD | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDH19 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 52/430 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, varscan2
- CDHR4 | c.2041T>A p.F681I | Missense Mutation (SNP) | VAF 62/465 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CDKL1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDX1 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 78/498 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CFHR3 | c.173_174del p.H58Lfs*2 | Frame Shift Del (DEL) | VAF 36/162 reads (22%) | called by mutect2, pindel, varscan2
- CGN | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA6 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CLSTN1 | c.857A>G p.N286S (on ENST00000377298 / NM_001009566.3; = p.N276S on NM_014944.4) | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL19A1 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL19A1 | c.3259G>A p.G1087R | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- COL6A1 | c.292_294del p.E98del | In Frame Del (DEL) | VAF 50/403 reads (12%) | called by mutect2, pindel, varscan2
- CORIN | c.2026G>A p.G676S | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMGDH | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- EBLN2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ELAPOR1 | c.1856A>C p.H619P | Missense Mutation (SNP) | VAF 91/470 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- EPAS1 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- EPHA1 | c.2926G>A p.D976N | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- FAT4 | c.11420C>T p.S3807F | Missense Mutation (SNP) | VAF 71/437 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FBXO21 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GREB1L | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GUCY1A2 | c.710T>A p.L237H | Missense Mutation (SNP) | VAF 102/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR1 | c.4690C>T p.L1564F (on ENST00000354582; = p.L1549F on NM_002222.7) | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- JAKMIP1 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KIAA1109 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- LIPF | c.279G>A p.W93* | Nonsense Mutation (SNP) | VAF 61/331 reads (18%) | called by muse, mutect2, varscan2
- MAGEB5 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 80/515 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- MCF2 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 63/494 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MMP26 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MT1G | c.28G>A p.A10T (on ENST00000379811 / NM_001301267.2; = p.G10S on NM_005950.3) | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTOR | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 137/468 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUC16 | c.39520A>C p.T13174P | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.608del p.K203Rfs*8 | Frame Shift Del (DEL) | VAF 70/477 reads (15%) | called by mutect2, pindel, varscan2
- MYO18B | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 49/343 reads (14%) | called by muse, mutect2, varscan2
- NDUFB11 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 65/450 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NFAT5 | c.3883del p.Q1295Kfs*24 | Frame Shift Del (DEL) | VAF 62/373 reads (17%) | called by mutect2, pindel, varscan2
- NRDC | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- NTN5 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- OR52N2 | c.286T>C p.F96L | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR52R1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 162/498 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PATL1 | c.537_547del p.P180Qfs*5 | Frame Shift Del (DEL) | VAF 48/492 reads (10%) | called by mutect2, pindel
- PAX7 | c.1072T>C p.F358L | Missense Mutation (SNP) | VAF 148/619 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PJA2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- PLA2G4D | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 67/470 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNA2 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 105/388 reads (27%) | called by muse, mutect2, varscan2
- PRSS54 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 71/434 reads (16%) | called by muse, mutect2, varscan2
- PTGIR | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 104/563 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PTPRB | c.2890C>T p.H964Y | Missense Mutation (SNP) | VAF 82/428 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAB41 | c.255G>A p.W85* (on ENST00000374473 / NM_001363807.1; = p.W84* on NM_001032726.3) | Nonsense Mutation (SNP) | VAF 72/412 reads (17%) | called by muse, mutect2, varscan2
- RBM39 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2
- RBM45 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- RIMBP2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 69/518 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMBP2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 70/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF214 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RNF214 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RYR2 | c.6541G>A p.G2181S | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2
- SATB1 | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 63/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SCAF1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELENOP | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A9 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 137/543 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC17A9 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 59/515 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SLC46A3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC7A2 | c.260C>T p.A87V (on ENST00000494857 / NM_001370338.1; = p.A127V on NM_003046.6) | Missense Mutation (SNP) | VAF 75/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SOCS4 | c.463A>C p.N155H | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SORL1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SRD5A2 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- TGM7 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TREX1 | c.140C>T p.P47L (on ENST00000625293 / NM_033629.6; = p.P37L on NM_007248.5) | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by mutect2, varscan2
- TRIML1 | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTBK1 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 94/600 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTN | c.47946G>A p.M15982I (on ENST00000591111; = p.M8558I on NM_003319.4) | Missense Mutation (SNP) | VAF 46/361 reads (13%) | PolyPhen benign (0.033); called by muse, mutect2, varscan2
- USH2A | c.15004G>A p.G5002R | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP11 | c.2362T>C p.F788L (on ENST00000218348; = p.F745L on NM_001371072.1) | Missense Mutation (SNP) | VAF 43/415 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VAT1L | c.1257G>C p.Q419H | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCAN | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF236 | c.3692C>T p.A1231V | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ZNF324 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF398 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 117/393 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF516 | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ZNF684 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF780B | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, varscan2
- ADAM19 | c.2835G>A p.R945= | Silent (SNP) | VAF 60/382 reads (16%) | called by muse, mutect2, varscan2
- ADGRF4 | c.114C>T p.S38= | Silent (SNP) | VAF 36/291 reads (12%) | called by muse, mutect2, varscan2
- APC2 | c.3123G>A p.E1041= | Silent (SNP) | VAF 76/503 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.2661C>T p.V887= (on ENST00000310343 / NM_001378025.1; = p.V538= on NM_014715.4) | Silent (SNP) | VAF 69/477 reads (14%) | catalogued as rs1052329603, COSV59843135; called by muse, mutect2, varscan2
- ARID2 | c.507C>T p.L169= | Silent (SNP) | VAF 52/353 reads (15%) | called by muse, mutect2, varscan2
- ARID3A | c.1275C>T p.A425= | Silent (SNP) | VAF 70/481 reads (15%) | called by muse, mutect2, varscan2
- ARMC7 | c.468C>T p.L156= | Silent (SNP) | VAF 83/532 reads (16%) | catalogued as COSV55460601; called by muse, mutect2, varscan2
- ARPP21 | c.138G>A p.L46= | Silent (SNP) | VAF 33/278 reads (12%) | catalogued as COSV99491657; called by muse, mutect2, varscan2
- C2orf16 | c.3033C>T p.V1011= | Silent (SNP) | VAF 37/248 reads (15%) | called by muse, mutect2, varscan2
- CA13 | c.117G>A p.V39= | Silent (SNP) | VAF 46/352 reads (13%) | called by muse, mutect2, varscan2
- CCDC115 | c.468C>T p.N156= | Silent (SNP) | VAF 44/346 reads (13%) | catalogued as COSV52092842; called by muse, mutect2, varscan2
- CCDC87 | c.1323C>T p.V441= | Silent (SNP) | VAF 160/529 reads (30%) | catalogued as COSV59579992; called by muse, mutect2, varscan2
- CCR2 | c.921C>T p.F307= | Silent (SNP) | VAF 54/390 reads (14%) | catalogued as rs1236408585, COSV52749614; called by muse, mutect2, varscan2
- CDC42BPG | c.4230C>T p.F1410= | Silent (SNP) | VAF 114/451 reads (25%) | catalogued as rs1457778787, COSV61347115; called by muse, mutect2, varscan2
- CDH9 | c.2082T>C p.P694= | Silent (SNP) | VAF 45/331 reads (14%) | called by muse, mutect2, varscan2
- CNGB1 | c.1383G>A p.T461= | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as rs773350723, COSV51906672; called by muse, mutect2, varscan2
- CNR1 | c.522C>T p.F174= | Silent (SNP) | VAF 79/378 reads (21%) | catalogued as rs946198796, COSV62986513; called by muse, mutect2, varscan2
- COL20A1 | c.417C>T p.S139= | Silent (SNP) | VAF 79/717 reads (11%) | called by muse, mutect2, varscan2
- COL23A1 | c.801G>A p.R267= | Silent (SNP) | VAF 72/498 reads (14%) | called by muse, mutect2, varscan2
- D2HGDH | c.438C>T p.I146= | Silent (SNP) | VAF 62/465 reads (13%) | called by muse, mutect2, varscan2
- DIRAS1 | c.231C>T p.S77= | Silent (SNP) | VAF 66/485 reads (14%) | called by muse, mutect2, varscan2
- DMBT1 | c.1695G>A p.G565= | Silent (SNP) | VAF 75/438 reads (17%) | catalogued as rs975332713; called by muse, mutect2, varscan2
- DNAH17 | c.3534C>T p.T1178= | Silent (SNP) | VAF 51/313 reads (16%) | catalogued as rs1284106372; called by muse, mutect2, varscan2
- DNAH9 | c.6364C>T p.L2122= | Silent (SNP) | VAF 41/326 reads (13%) | called by muse, mutect2, varscan2
- DNMBP | c.3549C>T p.V1183= | Silent (SNP) | VAF 77/332 reads (23%) | called by muse, mutect2, varscan2
- DROSHA | c.4026G>T p.R1342= | Silent (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- ELAVL1 | c.828C>T p.I276= | Silent (SNP) | VAF 67/432 reads (16%) | catalogued as COSV60967348; called by muse, mutect2, varscan2
- EPHA7 | c.1968G>A p.G656= | Silent (SNP) | VAF 52/362 reads (14%) | catalogued as COSV65180377; called by muse, mutect2, varscan2
- F8 | c.2481C>T p.L827= | Silent (SNP) | VAF 63/414 reads (15%) | catalogued as rs1000290380; called by muse, mutect2, varscan2
- FAXC | c.732C>T p.R244= | Silent (SNP) | VAF 58/368 reads (16%) | catalogued as rs780598954, COSV67601718; called by muse, mutect2, varscan2
- FBN1 | c.717C>T p.I239= | Silent (SNP) | VAF 48/347 reads (14%) | called by muse, mutect2, varscan2
- FOXN4 | c.1425C>T p.S475= | Silent (SNP) | VAF 78/477 reads (16%) | catalogued as rs1207240915, COSV54497812; called by muse, mutect2, varscan2
- GCN1 | c.2415C>T p.I805= | Silent (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- GLI3 | c.1473C>T p.F491= | Silent (SNP) | VAF 87/361 reads (24%) | catalogued as rs572462647, COSV67889215, COSV67895136; called by muse, mutect2, varscan2
- GPRIN2 | c.66C>T p.S22= | Silent (SNP) | VAF 46/724 reads (6%) | catalogued as COSV100966354; called by muse, mutect2
- GPT2 | c.1071C>T p.I357= | Silent (SNP) | VAF 38/428 reads (9%) | called by muse, mutect2
- GRIK3 | c.1743C>T p.F581= | Silent (SNP) | VAF 47/326 reads (14%) | catalogued as rs746513520; called by muse, mutect2, varscan2
- IGLV1-44 | c.18C>T p.L6= | Silent (SNP) | VAF 42/322 reads (13%) | called by muse, varscan2
- KCNJ4 | c.288G>A p.A96= | Silent (SNP) | VAF 83/556 reads (15%) | catalogued as rs764694400; called by muse, mutect2, varscan2
- KIF4B | c.3408G>A p.Q1136= | Silent (SNP) | VAF 83/548 reads (15%) | catalogued as COSV70530263; called by muse, mutect2, varscan2
- KIFC1 | c.513C>T p.L171= | Silent (SNP) | VAF 108/632 reads (17%) | catalogued as rs1562834997; called by muse, mutect2, varscan2
- KIRREL1 | c.1917C>T p.S639= | Silent (SNP) | VAF 69/525 reads (13%) | catalogued as rs745306420; called by muse, mutect2, varscan2
- KLK6 | c.492C>T p.S164= | Silent (SNP) | VAF 63/415 reads (15%) | catalogued as COSV100037810; called by muse, mutect2, varscan2
- LEMD3 | c.1293C>T p.G431= | Silent (SNP) | VAF 46/343 reads (13%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4518C>T p.F1506= | Silent (SNP) | VAF 43/262 reads (16%) | catalogued as rs1243080451, COSV100191145; called by muse, mutect2, varscan2
- LPAR3 | c.141T>G p.S47= | Silent (SNP) | VAF 58/352 reads (16%) | called by mutect2, varscan2
- LRRC53 | c.153A>G p.T51= | Silent (SNP) | VAF 51/385 reads (13%) | called by muse, mutect2, varscan2
- LRRK1 | c.1929C>T p.I643= | Silent (SNP) | VAF 74/438 reads (17%) | catalogued as rs773600020, COSV52622589; called by muse, varscan2
- MED12 | c.4992G>A p.K1664= | Silent (SNP) | VAF 70/385 reads (18%) | catalogued as rs1198568939; called by muse, mutect2, varscan2
- MS4A3 | c.252C>T p.F84= | Silent (SNP) | VAF 85/382 reads (22%) | catalogued as COSV53935591; called by muse, mutect2, varscan2
- MUC12 | c.16194C>T p.I5398= (on ENST00000379442; = p.I5255= on NM_001164462.1) | Silent (SNP) | VAF 51/407 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.15723C>T p.S5241= | Silent (SNP) | VAF 52/394 reads (13%) | catalogued as COSV67482591; called by muse, mutect2, varscan2
- MXRA5 | c.1335G>A p.Q445= | Silent (SNP) | VAF 64/446 reads (14%) | catalogued as COSV54239239; called by muse, mutect2, varscan2
- NCK1 | c.535T>C p.L179= | Silent (SNP) | VAF 48/296 reads (16%) | called by muse, mutect2, varscan2
- NCKAP1 | c.1383C>T p.S461= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as rs71427865; called by muse, mutect2, varscan2
- NCKAP5L | c.549C>T p.F183= | Silent (SNP) | VAF 78/536 reads (15%) | called by muse, mutect2, varscan2
- NEFM | c.1290C>T p.I430= | Silent (SNP) | VAF 48/364 reads (13%) | called by muse, mutect2, varscan2
- NXPH1 | c.519C>T p.I173= | Silent (SNP) | VAF 137/490 reads (28%) | catalogued as rs202131987; called by muse, mutect2, varscan2
- OAS2 | c.1305C>T p.I435= | Silent (SNP) | VAF 73/420 reads (17%) | catalogued as rs1310725602; called by muse, mutect2, varscan2
- OR10J5 | c.891G>A p.K297= | Silent (SNP) | VAF 35/326 reads (11%) | catalogued as rs149827201, COSV58386260, COSV58386328; called by muse, mutect2, varscan2
- OR1F1 | c.315C>T p.F105= | Silent (SNP) | VAF 53/407 reads (13%) | catalogued as COSV100484509; called by muse, mutect2, varscan2
- OR2T34 | c.27G>A p.Q9= | Silent (SNP) | VAF 82/676 reads (12%) | called by muse, mutect2, varscan2
- OR51E2 | c.240C>T p.I80= | Silent (SNP) | VAF 54/527 reads (10%) | catalogued as COSV67808886; called by muse, mutect2, varscan2
- OR52N2 | c.429C>T p.I143= | Silent (SNP) | VAF 118/438 reads (27%) | catalogued as rs764151894, COSV57676493, COSV57677519; called by muse, mutect2, varscan2
- OR56A5 | c.252C>T p.V84= | Silent (SNP) | VAF 163/581 reads (28%) | catalogued as COSV60828063; called by muse, mutect2, varscan2
- ORMDL3 | c.285C>T p.F95= | Silent (SNP) | VAF 42/402 reads (10%) | catalogued as rs752570109, COSV100401491; called by muse, mutect2, varscan2
- OSGEPL1 | c.682T>C p.L228= | Silent (SNP) | VAF 58/376 reads (15%) | catalogued as rs1302062748; called by muse, mutect2, varscan2
- P4HB | c.705C>T p.P235= | Silent (SNP) | VAF 48/380 reads (13%) | called by muse, mutect2, varscan2
- PCDHB7 | c.2118C>T p.F706= | Silent (SNP) | VAF 144/1445 reads (10%) | catalogued as rs868962799, COSV50753682; called by muse, mutect2
- PLCB2 | c.2067C>T p.I689= | Silent (SNP) | VAF 38/227 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.2637C>G p.A879= (on ENST00000283426; = p.A1235= on NM_052909.5) | Silent (SNP) | VAF 50/371 reads (13%) | called by muse, mutect2, varscan2
- POLH | c.1818C>A p.A606= | Silent (SNP) | VAF 59/414 reads (14%) | called by muse, mutect2, varscan2
- PTER | c.9C>T p.S3= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- RAC3 | c.273G>A p.E91= | Silent (SNP) | VAF 47/353 reads (13%) | catalogued as rs750977288; called by muse, mutect2, varscan2
- RASL11A | c.210C>T p.V70= | Silent (SNP) | VAF 60/297 reads (20%) | catalogued as rs1363947339; called by muse, mutect2, varscan2
- RBM10 | c.2544C>T p.F848= | Silent (SNP) | VAF 61/448 reads (14%) | catalogued as rs782028481, COSV61307969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB3 | c.1239C>T p.F413= | Silent (SNP) | VAF 41/336 reads (12%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2274G>A p.E758= | Silent (SNP) | VAF 71/370 reads (19%) | called by muse, mutect2, varscan2
- S100A13 | c.276C>T p.D92= | Silent (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- SCUBE3 | c.339G>A p.V113= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as COSV99234494; called by muse, mutect2, varscan2
- SDC4 | c.297C>T p.V99= | Silent (SNP) | VAF 51/417 reads (12%) | called by muse, mutect2, varscan2
- SEC14L5 | c.81C>T p.F27= | Silent (SNP) | VAF 50/319 reads (16%) | catalogued as COSV99229479; called by muse, mutect2, varscan2
- SEMA6B | c.117G>A p.R39= | Silent (SNP) | VAF 43/292 reads (15%) | called by muse, mutect2, varscan2
- SEMA6C | c.2406C>T p.A802= | Silent (SNP) | VAF 77/423 reads (18%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1248C>T p.S416= | Silent (SNP) | VAF 43/328 reads (13%) | catalogued as rs377305245, COSV54110958, COSV54123548; called by muse, mutect2, varscan2
- SLC28A1 | c.495C>T p.V165= | Silent (SNP) | VAF 54/379 reads (14%) | called by muse, mutect2, varscan2
- SMAD7 | c.714G>A p.T238= | Silent (SNP) | VAF 56/373 reads (15%) | catalogued as rs376292728; called by muse, mutect2, varscan2
- SPTBN2 | c.216C>T p.A72= | Silent (SNP) | VAF 177/589 reads (30%) | called by muse, mutect2, varscan2
- SRRT | c.390C>T p.I130= | Silent (SNP) | VAF 36/327 reads (11%) | catalogued as COSV61451977; called by muse, varscan2
- SV2B | c.339C>T p.F113= | Silent (SNP) | VAF 41/413 reads (10%) | catalogued as rs777632691, COSV57698821, COSV57699712; called by muse, mutect2, varscan2
- SYNJ1 | c.9G>A p.K3= | Silent (SNP) | VAF 45/353 reads (13%) | catalogued as rs1250657533, COSV59144673; called by muse, mutect2, varscan2
- TAS2R9 | c.612C>T p.S204= | Silent (SNP) | VAF 102/463 reads (22%) | catalogued as COSV53690690; called by muse, mutect2, varscan2
- TIAM1 | c.414C>T p.D138= | Silent (SNP) | VAF 77/484 reads (16%) | catalogued as rs765881295, COSV54536633; called by muse, mutect2, varscan2
- TNIP1 | c.870C>T p.V290= | Silent (SNP) | VAF 60/320 reads (19%) | called by muse, mutect2
- TNS2 | c.1887C>T p.S629= (on ENST00000314250 / NM_170754.4; = p.S639= on NM_015319.2) | Silent (SNP) | VAF 98/466 reads (21%) | catalogued as COSV58576185; called by muse, mutect2, varscan2
- TREX1 | c.141C>T p.P47= (on ENST00000625293 / NM_033629.6; = p.P37= on NM_007248.5) | Silent (SNP) | VAF 78/525 reads (15%) | catalogued as COSV99604146; called by mutect2, varscan2
- TRGV2 | c.174G>A p.E58= | Silent (SNP) | VAF 49/488 reads (10%) | called by muse, mutect2, varscan2
- TRHDE | c.2247G>A p.K749= | Silent (SNP) | VAF 46/364 reads (13%) | catalogued as COSV99671861, COSV99671976; called by muse, mutect2, varscan2
- TRIM3 | c.186C>T p.C62= | Silent (SNP) | VAF 151/507 reads (30%) | called by muse, mutect2, varscan2
- TRPV5 | c.1203C>T p.L401= | Silent (SNP) | VAF 48/463 reads (10%) | catalogued as rs267601355; called by muse, mutect2, varscan2
- TXK | c.1182G>A p.R394= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as COSV51920068; called by muse, mutect2, varscan2
- UBQLN3 | c.1456C>T p.L486= | Silent (SNP) | VAF 163/550 reads (30%) | catalogued as COSV61164395; called by muse, mutect2, varscan2
- UGT2A1 | c.747G>A p.G249= | Silent (SNP) | VAF 42/283 reads (15%) | called by muse, mutect2, varscan2
- VPS9D1 | c.951C>T p.T317= | Silent (SNP) | VAF 105/494 reads (21%) | called by mutect2, varscan2
- ZFHX4 | c.3366T>A p.L1122= | Silent (SNP) | VAF 56/327 reads (17%) | called by muse, mutect2, varscan2
- ZNF324 | c.768C>T p.S256= | Silent (SNP) | VAF 70/471 reads (15%) | called by muse, mutect2, varscan2
- ZNF496 | c.1164C>T p.S388= | Silent (SNP) | VAF 158/594 reads (27%) | catalogued as COSV54175855; called by muse, mutect2, varscan2
- DCAF8 | c.-236G>A | 5'UTR (SNP) | VAF 48/387 reads (12%) | called by muse, mutect2, varscan2
- DST | c.4296+4536G>A | Intron (SNP) | VAF 57/416 reads (14%) | called by muse, mutect2, varscan2
- DTNBP1 | c.511+7337C>T | Intron (SNP) | VAF 40/290 reads (14%) | catalogued as rs1561975510; called by muse, mutect2, varscan2
- JUP | c.*14+27C>T | Intron (SNP) | VAF 72/506 reads (14%) | catalogued as COSV100159557; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+28587C>A | Intron (SNP) | VAF 35/320 reads (11%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-89C>T | Intron (SNP) | VAF 88/522 reads (17%) | called by muse, mutect2, varscan2
- MCF2 | chrX:139645569 G>A | 5'Flank (SNP) | VAF 48/263 reads (18%) | catalogued as COSV100644694, COSV58492691; called by muse, mutect2, varscan2
- NUDT16L1 | c.414+26C>T | Intron (SNP) | VAF 89/569 reads (16%) | catalogued as rs1220425297; called by muse, mutect2, varscan2
- PER1 | c.2461+137G>A | Intron (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- TTC6 | chr14:37790826 T>A | 5'Flank (SNP) | VAF 32/201 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+4083G>A | Intron (SNP) | VAF 25/253 reads (10%) | catalogued as COSV100598233; called by muse, mutect2, varscan2
- WDR49 | c.-65-22535C>T | Intron (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- ZNF624 | chr17:16617136 A>G | 3'Flank (SNP) | VAF 79/458 reads (17%) | called by muse, mutect2, varscan2
